Somatic mutation profile of tumor specimen TARGET-40-NAAWDK-01A (aliquot TARGET-40-NAAWDK-01A-01D) from TARGET case TARGET-40-NAAWDK, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.0 years (6,205 days).
Specimen TARGET-40-NAAWDK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a20a1d6-8e6f-4f40-add8-7456d1cec247.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWDK-10A (Blood Derived Normal), aliquot TARGET-40-NAAWDK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cb5a894-efd6-4411-a232-f951797c9564

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF20B | c.3520_3523del p.K1174Lfs*9 (on ENST00000371728 / NM_001284259.2; = p.K1134Lfs*9 on NM_016195.4) | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- NDUFA12 | c.350T>A p.V117E | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- OBSCN | c.15700T>A p.S5234T | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PRPF39 | c.1681_1724del p.L561Ifs*3 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel
- ZNF233 | c.1504C>G p.H502D | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1B | c.1869C>T p.F623= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1469811706, COSV53145049; called by muse, mutect2
- CCDC168 | c.10500G>T p.G3500= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- MAGOHB | c.117C>T p.N39= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs75611181; called by mutect2, varscan2
